Somatic mutation profile of tumor specimen MP2PRT-PARWHA-TMP1-A (aliquot MP2PRT-PARWHA-TMP1-A-1-0-D-A82L-36) from MP2PRT case MP2PRT-PARWHA, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: female; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 5.5 years (1,996 days).
Specimen MP2PRT-PARWHA-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 51db2368-ecc3-4985-a00f-693a058bfd18.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PARWHA-NM1-A (Blood Derived Cancer - Bone Marrow, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PARWHA-NM1-A-1-0-D-A82L-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a5ac596b-afdb-45d5-9e08-981170290ca3

The open-access MAF lists 15 somatic variants for this specimen: 10 protein-altering or splice-affecting, 4 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 7, Silent 4, Intron 1, Nonsense Mutation 1, Frame Shift Del 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.35G>T p.G12V | Missense Mutation (SNP) | VAF 92/299 reads (31%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- CDH6 | c.1328C>A p.S443* | Nonsense Mutation (SNP) | VAF 80/262 reads (31%) | catalogued as COSV54065993; called by muse, mutect2, varscan2
- LHX1 | c.1194dup p.E399Rfs*65 | Frame Shift Ins (INS) | VAF 186/533 reads (35%) | catalogued as rs775423572; called by mutect2, varscan2
- OR2A14 | c.821C>G p.S274C | Missense Mutation (SNP) | VAF 105/317 reads (33%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.976); catalogued as COSV68718457; called by muse, mutect2, varscan2
- PCDHA6 | c.1559T>C p.L520P | Missense Mutation (SNP) | VAF 337/884 reads (38%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as rs781841292; called by muse, mutect2, varscan2
- PDE4DIP | c.6419C>T p.T2140M | Missense Mutation (SNP) | VAF 12/27 reads (44%) | SIFT tolerated (0.1); PolyPhen benign (0.041); catalogued as rs587627879, COSV57684216; called by mutect2, varscan2
- PTCHD1 | c.1424C>T p.A475V | Missense Mutation (SNP) | VAF 229/625 reads (37%) | SIFT tolerated (0.6); PolyPhen benign (0.017); catalogued as rs1457232518, COSV104432292; called by muse, mutect2, varscan2
- AL592490.1 | c.1121A>T p.D374V | Missense Mutation (SNP) | VAF 146/390 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.864); called by muse, mutect2, varscan2
- IGHV3-53 | c.335_343delinsCT p.Y112Sfs*? | Frame Shift Del (DEL) | VAF 11/65 reads (17%) | called by muse*, pindel
- PGM2L1 | c.1205G>T p.G402V | Missense Mutation (SNP) | VAF 87/222 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- FBXW5 | c.1122G>A p.Q374= | Silent (SNP) | VAF 196/556 reads (35%) | called by muse, mutect2, varscan2
- LAMB3 | c.387C>T p.A129= | Silent (SNP) | VAF 186/526 reads (35%) | catalogued as rs374988953; ClinVar: likely benign; called by muse, mutect2
- OR2A14 | c.372C>T p.D124= | Silent (SNP) | VAF 133/326 reads (41%) | called by muse, mutect2, varscan2
- PTPN14 | c.1002G>A p.P334= | Silent (SNP) | VAF 108/308 reads (35%) | catalogued as rs745512581; called by muse, mutect2, varscan2
- ROBO2 | c.3761-2243G>T | Intron (SNP) | VAF 109/272 reads (40%) | called by muse, mutect2, varscan2
